Somatic mutation profile of tumor specimen MBCProject_0857_T2_WES (aliquot MBCProject_0857_T2_WES_1) from CMI case MBCProject_0857, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.6 years (13,014 days).
Specimen MBCProject_0857_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93954c86-c3bf-4307-99e1-b9ba2b76d5c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0857_SALIVA (Saliva), aliquot MBCProject_0857_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db2c1a9a-a9f6-475c-b9f4-84e62e54965d

The open-access MAF lists 298 somatic variants for this specimen: 194 protein-altering or splice-affecting, 68 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 68, Nonsense Mutation 23, Intron 18, 5'UTR 5, RNA 5, 5'Flank 4, Splice Site 3, Splice Region 3, 3'UTR 2, 3'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 138/297 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58132866; called by muse, mutect2, varscan2
- ACTN2 | c.702C>G p.I234M | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.991); catalogued as COSV63973570, COSV63976240; called by muse, varscan2
- ADAMTS19 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs766949011, COSV50755296; called by muse, mutect2, varscan2
- AGBL1 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759191613, COSV66848829; called by muse, mutect2, varscan2
- ANK2 | c.10264G>A p.E3422K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.301); catalogued as rs758710640, COSV52151167; called by muse, mutect2, varscan2
- AOAH | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV51746756, COSV51748031; called by muse, mutect2, varscan2
- ARFGEF2 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1335584622, COSV64211877; called by muse, mutect2
- ARMC3 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99957220; called by muse, mutect2, varscan2
- ATP6V1E2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1215886754; called by muse, mutect2, varscan2
- BRPF3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777211871; called by muse, mutect2, varscan2
- C2orf16 | c.4761G>C p.Q1587H | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV100820815; called by muse, mutect2, varscan2
- CASC3 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 80/1578 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as rs1424853364, COSV52869625; called by muse, mutect2
- CDC34 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs771514074, COSV52742922; called by muse, mutect2, varscan2
- CDC42EP4 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59961880; called by muse, mutect2
- CDK20 | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as COSV57481588; called by muse, mutect2, varscan2
- CDYL | c.643G>A p.E215K (on ENST00000328908 / NM_001368125.1; = p.E161K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/415 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs573123342, COSV59359409; called by muse, mutect2, varscan2
- CNOT6L | c.1360G>A p.G454R (on ENST00000504123 / NM_001286790.2; = p.G449R on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs1374003399, COSV53698762; called by muse, mutect2
- CPEB2 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT deleterious, low confidence (0); catalogued as rs1251933492; called by muse, mutect2
- CPT1C | c.2027C>A p.S676* | Nonsense Mutation (SNP) | VAF 27/146 reads (18%) | catalogued as COSV54920808; called by muse, mutect2, varscan2
- CSTF1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs777709245, COSV53858718; called by muse, varscan2
- CTAGE9 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 50/824 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV58418378; called by muse, mutect2
- DHX40 | c.2169G>T p.W723C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52067098; called by muse, mutect2, varscan2
- DMD | c.5413G>T p.V1805L | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as CD068545; called by muse, mutect2, varscan2
- DNAJC22 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs746978369, COSV101222588, COSV67713147; called by muse, mutect2
- DSEL | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.353); catalogued as COSV59490372; called by muse, mutect2, varscan2
- ECI1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100066463; called by muse, mutect2, varscan2
- EIF2AK3 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs905092644; called by muse, mutect2
- ELAVL2 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV56357220, COSV99807293; called by muse, mutect2, varscan2
- FAM160A1 | c.2971G>C p.E991Q | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV70709507; called by muse, mutect2, varscan2
- FAM186A | c.4457C>T p.P1486L | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1426491607, COSV59247568; called by muse, varscan2
- FBN3 | c.247G>C p.V83L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs532677935; called by muse, mutect2, varscan2
- FLT4 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56118408; called by muse, mutect2
- FOXC1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1294226013; called by muse, mutect2, varscan2
- GAB3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs1242626854, COSV65819160; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- GPR50 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV54437418; called by muse, mutect2, varscan2
- HAS1 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV55789732; called by muse, mutect2, varscan2
- HCN3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV64233658; called by muse, mutect2, varscan2
- HEATR5A | c.5042G>C p.G1681A | Missense Mutation (SNP) | VAF 275/445 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs954216097; called by muse, mutect2, varscan2
- HHIPL2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762521443, COSV58567164; called by muse, mutect2, varscan2
- IFT88 | c.688C>G p.Q230E (on ENST00000319980 / NM_001318493.2; = p.Q221E on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs1392662112; called by muse, mutect2, varscan2
- INTS1 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1300021041; called by muse, mutect2, varscan2
- KANK4 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1422115373; called by muse, varscan2
- KDM7A | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV50092050; called by muse, mutect2, varscan2
- KRT17P2 | n.673G>A | Splice Region (SNP) | VAF 42/155 reads (27%) | catalogued as rs1381906180; called by muse, mutect2, varscan2
- LHX2 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV65318316; called by muse, mutect2, varscan2
- LHX6 | c.437G>C p.R146T (on ENST00000373755 / NM_001242334.2; = p.R175T on NM_014368.5) | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61344660; called by muse, mutect2, varscan2
- LMTK3 | c.2440G>T p.E814* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99540248; called by muse, mutect2, varscan2
- LRCH4 | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53823418; called by muse, mutect2, varscan2
- MUC17 | c.2974C>T p.H992Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60299186; called by muse, mutect2, varscan2
- MUC4 | c.6263C>T p.S2088L | Missense Mutation (SNP) | VAF 82/701 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); catalogued as rs778773947; called by muse, varscan2
- MYO1B | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | catalogued as COSV100269441; called by muse, mutect2
- NUP155 | c.3814G>C p.E1272Q (on ENST00000231498 / NM_153485.3; = p.E1213Q on NM_004298.4) | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771713307; called by muse, mutect2, varscan2
- OCM2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs761101916; called by muse, mutect2, varscan2
- PABPC1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs747152709, COSV59408229; called by muse, mutect2, varscan2
- PKD1 | c.9333C>G p.F3111L | Missense Mutation (SNP) | VAF 54/465 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.113); catalogued as rs4787115; called by muse, mutect2, varscan2
- PLCB3 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs760018421; called by muse, mutect2, varscan2
- PLCD4 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs777377907; called by mutect2, varscan2
- POLQ | c.2919C>G p.F973L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99952077; called by muse, mutect2
- PRPH | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1208908386, COSV57679813; called by muse, mutect2, varscan2
- RAD23B | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs950956301, COSV100787798; called by muse, mutect2, varscan2
- RAE1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV64798570; called by muse, mutect2
- RASEF | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759532207; called by muse, mutect2, varscan2
- RBM33 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.443); catalogued as rs761167847; called by muse, mutect2, varscan2
- RBM38 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 103/1094 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs867171824, COSV100654875, COSV61133782; called by muse, mutect2
- RGS9 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 162/349 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1271937692, COSV99287630; called by muse, mutect2, varscan2
- RNF182 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101337840; called by muse, mutect2
- RTTN | c.3712C>G p.Q1238E | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV55342617; called by muse, mutect2
- SAMSN1 | c.779G>A p.G260D (on ENST00000647101; = p.G32D on NM_001256370.1) | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1444921468; called by muse, mutect2, varscan2
- SCAF11 | c.4173C>G p.I1391M | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65478010; called by muse, mutect2, varscan2
- SESN1 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 108/508 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs761108393; called by muse, mutect2, varscan2
- SLCO4A1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1438891165; called by muse, mutect2
- SOD2 | c.6G>C p.L2F | Missense Mutation (SNP) | VAF 107/478 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV61623265; called by muse, mutect2, varscan2
- SOS2 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as COSV53568095; called by muse, mutect2, varscan2
- SSH2 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 89/571 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52179448; called by muse, mutect2, varscan2
- SV2C | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59218954, COSV59226666; called by muse, mutect2, varscan2
- THADA | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360185311; called by muse, mutect2, varscan2
- TMEM248 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV58577760; called by muse, varscan2
- TRPC7 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.094); catalogued as rs1318378773; called by muse, mutect2
- WDR45B | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 114/515 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as rs771755275; called by muse, mutect2, varscan2
- XPO4 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55011414; called by muse, mutect2, varscan2
- ZFP41 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781397393; called by muse, mutect2, varscan2
- ZFP64 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99402938; called by muse, mutect2
- ZNF169 | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 44/140 reads (31%) | catalogued as COSV61763983; called by muse, mutect2, varscan2
- ZNF853 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 50/232 reads (22%) | catalogued as COSV101499468; called by muse, mutect2, varscan2
- APOL2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, mutect2
- ARHGAP5 | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARHGEF4 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARHGEF9 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- AURKC | c.582G>C p.L194= (on ENST00000302804 / NM_001015878.2; = p.L160= on NM_003160.3) | Splice Region (SNP) | VAF 28/432 reads (6%) | called by muse, mutect2
- B4GALT5 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- BEND2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1QTNF2 | c.871G>T p.E291* (on ENST00000393975; = p.E246* on NM_031908.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/288 reads (12%) | called by muse, mutect2, varscan2
- C20orf204 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 29/514 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- C7orf25 | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CABCOCO1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.795); called by muse, mutect2
- CACNA1E | c.4690-1G>T p.X1564_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CCDC190 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- CD6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.062); called by muse, mutect2
- CDKAL1 | c.541C>G p.Q181E | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP85L | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CLDN22 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- COL1A1 | c.3889G>T p.E1297* | Nonsense Mutation (SNP) | VAF 21/593 reads (4%) | called by muse, mutect2
- CPB1 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CRH | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 86/335 reads (26%) | called by muse, mutect2, varscan2
- CSPG4 | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DDX24 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DEF8 | c.283G>C p.E95Q (on ENST00000268676 / NM_207514.3; = p.E34Q on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.08); called by muse, mutect2
- DEPDC5 | c.2689G>A p.A897T (on ENST00000400246; = p.A966T on NM_014662.5) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- DHRS7C | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DHRS9 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAJC17 | c.148+3G>C | Splice Region (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- DPP9 | c.453C>A p.F151L (on ENST00000598800; = p.F180L on NM_139159.5) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DUSP5 | c.65G>C p.R22P | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); called by muse, varscan2
- EDC4 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- EGFL7 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- EIF3K | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.059); called by muse, mutect2
- EIF4G2 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2
- ERICH1 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM177A1 | c.32G>T p.R11L (on ENST00000382406 / NM_001289022.2; = p.R34L on NM_173607.5) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAXC | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FBXO16 | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGA | c.1950C>G p.I650M | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FLYWCH1 | c.595T>G p.L199V (on ENST00000253928 / NM_001308068.2; = p.L198V on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GABPA | c.749-1G>C p.X250_splice | Splice Site (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- GABRR2 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, varscan2
- GPR101 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5A | c.4963G>C p.E1655Q | Missense Mutation (SNP) | VAF 115/179 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- HERC6 | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- HIVEP3 | c.4214G>C p.R1405T | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HMCN2 | c.12010G>C p.E4004Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- HRNR | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- HS3ST4 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IARS2 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IRX3 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 74/118 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- JAK2 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- KLK2 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by mutect2, varscan2
- KRT26 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- LAMA2 | c.7266G>C p.W2422C | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMNB1 | c.1436C>A p.S479* | Nonsense Mutation (SNP) | VAF 62/215 reads (29%) | called by muse, mutect2, varscan2
- LONRF2 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- LPIN2 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRRC53 | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2
- LRRIQ4 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MACROD2 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP7 | c.1076C>G p.A359G | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MARK1 | c.1241C>G p.S414* | Nonsense Mutation (SNP) | VAF 51/150 reads (34%) | called by muse, mutect2, varscan2
- MBD5 | c.3504G>C p.K1168N | Missense Mutation (SNP) | VAF 105/349 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- METTL2A | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MFSD11 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MTMR3 | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- MYO1D | c.1805A>G p.D602G | Missense Mutation (SNP) | VAF 90/1080 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- NAXE | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- NEK8 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 118/794 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NYNRIN | c.5658G>C p.K1886N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PALLD | c.2536G>C p.D846H (on ENST00000505667 / NM_001166108.2; = p.D829H on NM_016081.4) | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PIK3R6 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PLCE1 | c.2653C>T p.Q885* | Nonsense Mutation (SNP) | VAF 83/294 reads (28%) | called by muse, mutect2, varscan2
- PNP | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- POGZ | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POLR3A | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by muse, mutect2
- POM121 | c.3689C>T p.S1230F (on ENST00000434423; = p.S965F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R15A | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRSS33 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PTBP1 | c.1507G>T p.E503* (on ENST00000349038 / NM_031991.4; = p.E529* on NM_002819.5) | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- R3HDM2 | c.1191dup p.L398Afs*32 | Frame Shift Ins (INS) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- RINT1 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 8/201 reads (4%) | called by muse, mutect2
- RNF128 | c.124G>C p.V42L | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPE | c.489G>C p.L163F (on ENST00000359429 / NM_001318926.1; = p.L113F on NM_006916.2) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RSPH1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2
- SEMA4C | c.75G>C p.W25C | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SFRP5 | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC26A8 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SLC30A10 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SMG1 | c.4648C>T p.Q1550* | Nonsense Mutation (SNP) | VAF 72/327 reads (22%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.975G>C p.Q325H | Missense Mutation (SNP) | VAF 100/519 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- SRP68 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 92/435 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- STOX2 | c.648G>T p.R216S | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SUSD4 | c.917-1G>A p.X306_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- TBCK | c.1219G>A p.D407N (on ENST00000273980 / NM_001163436.4; = p.D344N on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, varscan2
- TERT | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TESPA1 | c.1392G>T p.W464C (on ENST00000316577 / NM_001098815.3; = p.W326C on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TNK2 | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- TRIM31 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TRIM46 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTC28 | c.5162C>T p.S1721L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.051); called by muse, mutect2
- UTP14C | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 20/468 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- VCAM1 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WDR91 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 64/222 reads (29%) | called by muse, mutect2, varscan2
- ZNF438 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF451 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF664 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- ZNF782 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACACA | c.2196G>C p.V732= | Silent (SNP) | VAF 56/670 reads (8%) | called by muse, mutect2
- ACBD7 | c.186C>G p.L62= | Silent (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- ACSS1 | c.1260C>T p.I420= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs1189463781; called by muse, mutect2, varscan2
- ANKMY1 | c.478C>T p.L160= | Silent (SNP) | VAF 97/381 reads (25%) | called by muse, mutect2, varscan2
- ATG2A | c.2872C>T p.L958= | Silent (SNP) | VAF 48/146 reads (33%) | called by muse, mutect2, varscan2
- C11orf42 | c.432G>A p.V144= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs775067239; called by muse, mutect2, varscan2
- C17orf78 | c.102C>T p.I34= | Silent (SNP) | VAF 71/491 reads (14%) | called by muse, mutect2, varscan2
- CDH10 | c.1812C>T p.L604= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs771110844; called by muse, mutect2, varscan2
- CDK5R1 | c.93G>A p.Q31= | Silent (SNP) | VAF 17/311 reads (5%) | catalogued as COSV55579135; called by muse, mutect2
- CDKL5 | c.2958C>T p.F986= | Silent (SNP) | VAF 99/367 reads (27%) | catalogued as rs765366935, COSV66105922; called by muse, mutect2, varscan2
- CLIC6 | c.1527G>A p.V509= (on ENST00000360731 / NM_001317009.2; = p.V491= on NM_053277.3) | Silent (SNP) | VAF 41/154 reads (27%) | called by muse, mutect2, varscan2
- CRACR2A | c.1146G>A p.L382= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs765872014, COSV52916918, COSV99365618; called by muse, mutect2, varscan2
- CYP2A7 | c.1233C>T p.F411= | Silent (SNP) | VAF 51/206 reads (25%) | catalogued as rs754905098; called by muse, mutect2, varscan2
- DDX59 | c.1464G>A p.L488= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
- DHX34 | c.3372C>T p.C1124= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs572475082; called by muse, mutect2, varscan2
- ENTHD1 | c.1725C>T p.V575= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- ERBB4 | c.1956G>A p.L652= | Silent (SNP) | VAF 51/190 reads (27%) | catalogued as rs761028384, COSV53545119, COSV53553428; called by muse, mutect2, varscan2
- FOXO3B | c.153G>C p.G51= | Silent (SNP) | VAF 36/135 reads (27%) | called by muse, varscan2
- FXYD1 | c.45C>T p.L15= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- GPAT4 | c.30G>A p.L10= | Silent (SNP) | VAF 40/157 reads (25%) | called by muse, varscan2
- HSP90AB1 | c.1743C>T p.S581= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs768782599; called by muse, mutect2, varscan2
- IFT80 | c.1692G>A p.V564= | Silent (SNP) | VAF 72/253 reads (28%) | called by muse, mutect2, varscan2
- IGHD | c.996C>T p.T332= | Silent (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- INTS1 | c.2595C>G p.L865= | Silent (SNP) | VAF 48/245 reads (20%) | catalogued as rs1245436061; called by muse, mutect2, varscan2
- KCNQ5 | c.1563C>A p.V521= | Silent (SNP) | VAF 60/162 reads (37%) | called by muse, varscan2
- KIF21A | c.2016G>A p.Q672= (on ENST00000361418 / NM_001378440.1; = p.Q659= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/215 reads (31%) | called by muse, mutect2, varscan2
- KIZ | c.312G>A p.L104= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, varscan2
- LILRB1 | c.1026G>A p.E342= (on ENST00000427581; = p.E306= on NM_006669.6) | Silent (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- LMTK3 | c.3990C>G p.L1330= | Silent (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- LRIG2 | c.2469C>T p.I823= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs753018088; called by muse, mutect2, varscan2
- LRRTM4 | c.987C>T p.F329= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- LTBP1 | c.3486C>T p.I1162= (on ENST00000404816 / NM_206943.4; = p.I836= on NM_000627.4) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV55375778, COSV99698079; called by muse, mutect2
- MBTPS2 | c.699C>G p.L233= | Silent (SNP) | VAF 103/665 reads (15%) | called by muse, mutect2, varscan2
- MEI1 | c.3492G>A p.E1164= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as COSV55909583; called by muse, mutect2, varscan2
- MROH1 | c.4638C>T p.F1546= | Silent (SNP) | VAF 78/209 reads (37%) | catalogued as rs1354900835; called by muse, mutect2, varscan2
- OR14A2 | c.129C>A p.I43= | Silent (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- OR51I2 | c.261C>T p.L87= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- P2RY1 | c.273C>T p.F91= | Silent (SNP) | VAF 56/213 reads (26%) | called by muse, mutect2, varscan2
- PCMTD2 | c.699C>G p.V233= | Silent (SNP) | VAF 46/778 reads (6%) | called by muse, mutect2
- PIKFYVE | c.4590G>C p.L1530= | Silent (SNP) | VAF 71/263 reads (27%) | called by muse, varscan2
- PLEKHG4B | c.2901C>G p.L967= (on ENST00000283426; = p.L1323= on NM_052909.5) | Silent (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- PPIL2 | c.348C>T p.I116= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as rs369102532, COSV58605948; called by muse, mutect2, varscan2
- PROP1 | c.321C>T p.G107= | Silent (SNP) | VAF 37/175 reads (21%) | called by muse, mutect2, varscan2
- PRX | c.171C>T p.L57= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- PTGER3 | c.558C>T p.L186= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs766776709; called by mutect2, varscan2
- RAD54B | c.2541C>T p.V847= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as rs1422767050; called by muse, mutect2, varscan2
- RNF17 | c.789C>T p.I263= | Silent (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- RSC1A1 | c.669G>A p.Q223= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs553352701; called by muse, mutect2, varscan2
- S100A5 | c.102C>G p.L34= | Silent (SNP) | VAF 15/233 reads (6%) | called by muse, mutect2
- SCAMP5 | c.615G>A p.Q205= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- SCG3 | c.930G>A p.V310= | Silent (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1281C>T p.Y427= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- SLC23A1 | c.1020C>T p.Y340= | Silent (SNP) | VAF 59/198 reads (30%) | catalogued as rs776506562, COSV100811901; called by muse, mutect2, varscan2
- SLC25A33 | c.558C>T p.F186= | Silent (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- SSC5D | c.294C>G p.L98= | Silent (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- SSNA1 | c.249C>G p.L83= | Silent (SNP) | VAF 68/221 reads (31%) | called by muse, mutect2, varscan2
- TBX2 | c.543G>A p.E181= | Silent (SNP) | VAF 79/347 reads (23%) | called by muse, mutect2, varscan2
- TGM4 | c.1887C>T p.I629= | Silent (SNP) | VAF 58/154 reads (38%) | called by muse, mutect2, varscan2
- TKTL2 | c.1215A>T p.R405= | Silent (SNP) | VAF 77/396 reads (19%) | called by muse, mutect2, varscan2
- TRDN | c.1074C>T p.T358= | Silent (SNP) | VAF 83/249 reads (33%) | called by muse, mutect2, varscan2
- TTI1 | c.1464G>A p.L488= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as COSV65063695; called by muse, mutect2
- TTN | c.37503G>A p.L12501= (on ENST00000591111; = p.L5077= on NM_003319.4) | Silent (SNP) | VAF 63/207 reads (30%) | catalogued as COSV59941829; called by muse, mutect2, varscan2
- URB2 | c.1806C>T p.V602= | Silent (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- USF3 | c.1812C>G p.L604= | Silent (SNP) | VAF 25/296 reads (8%) | called by muse, mutect2
- USP41 | c.345G>A p.Q115= | Silent (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- VPS33A | c.1533C>T p.I511= | Silent (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- WDFY1 | c.156G>A p.L52= | Silent (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- ZNF317 | c.1215G>A p.R405= | Silent (SNP) | VAF 43/162 reads (27%) | called by muse, mutect2, varscan2
- ACER3 | c.215-1505C>G | Intron (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- ADCK2 | chr7:140695779 del CA | 3'Flank (DEL) | VAF 18/78 reads (23%) | catalogued as rs761766469; called by pindel, varscan2
- AL359922.1 | c.348-35177G>T | Intron (SNP) | VAF 37/81 reads (46%) | catalogued as COSV64253531; called by muse, mutect2, varscan2
- ARHGEF1 | c.-20+1188C>G | Intron (SNP) | VAF 46/244 reads (19%) | called by muse, mutect2, varscan2
- ASB18 | c.205+4618G>A | Intron (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- BBS1 | c.160-18G>C | Intron (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38327G>A | Intron (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- CFAP100 | c.225+9C>G | Intron (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- CGB7 | c.-1035C>T | 5'UTR (SNP) | VAF 26/210 reads (12%) | called by muse, mutect2, varscan2
- CSPG4 | c.4951-878G>A | Intron (SNP) | VAF 42/206 reads (20%) | catalogued as rs376845947; called by muse, mutect2, varscan2
- DCTN6 | chr8:30156356 C>G | 5'Flank (SNP) | VAF 16/154 reads (10%) | catalogued as rs762528872; called by muse, mutect2, varscan2
- DPY19L2P2 | n.3181G>A | RNA (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- ENTPD5 | chr14:73959137 G>A | 3'Flank (SNP) | VAF 136/308 reads (44%) | catalogued as rs769879475; called by muse, mutect2, varscan2
- FAM207A | chr21:44939578 C>T | 5'Flank (SNP) | VAF 16/399 reads (4%) | called by muse, mutect2
- GRIK5 | c.2514+1177C>G | Intron (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2
- HMBS | c.651+52C>T | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- HSPG2 | c.7873+51G>A | Intron (SNP) | VAF 8/170 reads (5%) | catalogued as rs1009621463; called by muse, mutect2
- LINC02076 | n.506C>G | RNA (SNP) | VAF 103/567 reads (18%) | called by muse, mutect2, varscan2
- MAN2B1 | c.1110-20C>G | Intron (SNP) | VAF 93/365 reads (25%) | called by muse, mutect2, varscan2
- MAP7 | c.68-44996G>C | Intron (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- MBNL1 | c.-1206C>G | 5'UTR (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- PAPOLA | c.-171G>T | 5'UTR (SNP) | VAF 30/73 reads (41%) | catalogued as rs1159529216; called by muse, mutect2, varscan2
- PDPR | c.1191-45C>G | Intron (SNP) | VAF 15/287 reads (5%) | called by muse, mutect2
- PLP1 | c.191+24G>C | Intron (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- RASGEF1C | c.1084-714G>C | Intron (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- RNF170 | chr8:42896708 C>T | 5'Flank (SNP) | VAF 7/29 reads (24%) | catalogued as rs1484920659; called by muse, mutect2, varscan2
- RPL31P57 | n.138C>G | RNA (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- SCD | c.-1G>C | 5'UTR (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2, varscan2
- SDC1 | c.66+588C>T | Intron (SNP) | VAF 47/286 reads (16%) | catalogued as rs1291305254; called by muse, mutect2, varscan2
- SFT2D2 | c.*15T>C | 3'UTR (SNP) | VAF 58/200 reads (29%) | called by muse, mutect2, varscan2
- SNORD115-4 | n.41G>A | RNA (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- SPHK1 | c.-18G>C | 5'UTR (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- TMEFF1 | c.*7G>C | 3'UTR (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- UBBP4 | n.1071G>C | RNA (SNP) | VAF 24/259 reads (9%) | called by muse, mutect2, varscan2
- UBXN4 | c.83-594C>T | Intron (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439021 C>G | 5'Flank (SNP) | VAF 40/197 reads (20%) | called by muse, mutect2, varscan2
